Somatic mutation profile of tumor specimen MP2PRT-PASXLV-TBP1-A (aliquot MP2PRT-PASXLV-TBP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PASXLV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 10.7 years (3,896 days).
Specimen MP2PRT-PASXLV-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc62c8c2-b2fc-4418-b432-6b5ff37bbc77.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASXLV-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASXLV-NM1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d34f1093-5791-4091-b9b5-6c939f9424df

The open-access MAF lists 73 somatic variants for this specimen: 56 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 51, Silent 17, Nonsense Mutation 4, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.5060G>A p.R1687Q | Missense Mutation (SNP) | VAF 84/406 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as rs779068685, COSV99072958; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- ARHGAP20 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 56/228 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.28); catalogued as rs749855783, COSV52806698; called by muse, mutect2, varscan2
- CADPS | c.1287G>C p.E429D | Missense Mutation (SNP) | VAF 47/342 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as rs1490900778, COSV51905887; called by muse, mutect2, varscan2
- CC2D1A | c.486G>C p.K162N | Missense Mutation (SNP) | VAF 69/442 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58781416; called by muse, mutect2, varscan2
- CDC73 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV66465795; called by muse, mutect2, varscan2
- CENPF | c.8385G>A p.M2795I | Missense Mutation (SNP) | VAF 66/284 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753288669; called by muse, mutect2, varscan2
- COL11A2 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 237/676 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as rs761464756; called by muse, mutect2, varscan2
- CRISPLD1 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 104/448 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs541154941, COSV51544170; called by muse, mutect2, varscan2
- CYLC2 | c.748G>C p.D250H | Missense Mutation (SNP) | VAF 45/456 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs558649241, COSV66337669; called by muse, mutect2
- DOCK3 | c.5019G>C p.L1673F | Missense Mutation (SNP) | VAF 39/303 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as rs998997811; called by muse, mutect2, varscan2
- GSN | c.2303G>A p.W768* | Nonsense Mutation (SNP) | VAF 82/590 reads (14%) | catalogued as rs938702801; called by muse, mutect2, varscan2
- HYDIN | c.3775G>C p.D1259H | Missense Mutation (SNP) | VAF 49/245 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as COSV66832081; called by muse, mutect2, varscan2
- KRT222 | c.688G>C p.E230Q | Missense Mutation (SNP) | VAF 34/223 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.039); catalogued as COSV67498205; called by muse, mutect2, varscan2
- MARCHF11 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 208/915 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100198319; called by muse, mutect2, varscan2
- NABP2 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 96/316 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs759250167, COSV57191821; called by muse, mutect2, varscan2
- NISCH | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 52/262 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61899414, COSV61900958; called by muse, mutect2, varscan2
- OR10K1 | c.195C>G p.I65M | Missense Mutation (SNP) | VAF 78/458 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.264); catalogued as COSV56870562; called by muse, mutect2, varscan2
- PCDHB2 | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 94/779 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.041); catalogued as rs781922167; called by muse, mutect2, varscan2
- PRDM9 | c.1430C>T p.S477F | Missense Mutation (SNP) | VAF 38/443 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV57002525; called by muse, mutect2
- SLC39A12 | c.1103G>C p.G368A | Missense Mutation (SNP) | VAF 49/381 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV66202829; called by muse, mutect2, varscan2
- SRCAP | c.9203G>A p.R3068H | Missense Mutation (SNP) | VAF 189/554 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); catalogued as rs1037838491; called by muse, mutect2, varscan2
- TOPAZ1 | c.3055G>A p.E1019K | Missense Mutation (SNP) | VAF 113/334 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs1012306252; called by muse, mutect2, varscan2
- TRIM42 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 34/377 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs753830695, COSV99647851; called by muse, mutect2
- TTN | c.10876G>C p.E3626Q (on ENST00000591111; = p.E3580Q on NM_003319.4) | Missense Mutation (SNP) | VAF 91/506 reads (18%) | catalogued as COSV100629329; called by muse, mutect2, varscan2
- YTHDC2 | c.3605C>T p.S1202L | Missense Mutation (SNP) | VAF 46/394 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs760012399, COSV50737299; called by muse, mutect2, varscan2
- ACOD1 | c.979G>C p.E327Q | Missense Mutation (SNP) | VAF 59/590 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2
- ANKH | c.800G>A p.G267D | Missense Mutation (SNP) | VAF 181/393 reads (46%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- ARMC4 | c.720G>C p.W240C | Missense Mutation (SNP) | VAF 52/528 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BEND3 | c.1581G>C p.K527N | Missense Mutation (SNP) | VAF 114/634 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2
- BEND3 | c.1486G>C p.D496H | Missense Mutation (SNP) | VAF 106/643 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2
- CMYA5 | c.8734G>C p.E2912Q | Missense Mutation (SNP) | VAF 65/483 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- DIP2A | c.3797G>T p.R1266M | Missense Mutation (SNP) | VAF 32/534 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- DMXL2 | c.5054C>G p.S1685* | Nonsense Mutation (SNP) | VAF 27/194 reads (14%) | called by muse, mutect2, varscan2
- DYNC2H1 | c.9014C>T p.S3005L | Missense Mutation (SNP) | VAF 64/376 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EMILIN3 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 177/518 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- FGFR1 | c.1090G>C p.E364Q (on ENST00000447712 / NM_023110.3; = p.E362Q on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/245 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- FILIP1L | c.2363G>A p.R788K (on ENST00000354552 / NM_182909.3; = p.R548K on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 98/454 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GTF3C1 | c.5707G>C p.D1903H | Missense Mutation (SNP) | VAF 87/592 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- LANCL1 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 62/399 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- LPCAT1 | c.1396G>C p.E466Q | Missense Mutation (SNP) | VAF 39/758 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.062); called by muse, mutect2
- MANEA | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 21/264 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.097); called by muse, mutect2
- PCDHB7 | c.1907C>T p.A636V | Missense Mutation (SNP) | VAF 86/3230 reads (3%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.012); called by muse, mutect2
- POT1 | c.1309C>T p.H437Y | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.124); called by muse, mutect2
- RAB37 | c.158C>A p.A53D | Missense Mutation (SNP) | VAF 115/389 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- RANBP9 | c.1025_1026insAG p.M342Ifs*13 | Frame Shift Ins (INS) | VAF 125/417 reads (30%) | called by mutect2, pindel, varscan2
- SLC4A4 | c.319C>T p.Q107* (on ENST00000264485 / NM_001098484.3; = p.Q63* on NM_003759.4) | Nonsense Mutation (SNP) | VAF 120/563 reads (21%) | called by muse, mutect2, varscan2
- SLIT3 | c.2181G>C p.E727D | Missense Mutation (SNP) | VAF 93/773 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPATA3 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 318/999 reads (32%) | SIFT deleterious, low confidence (0.04); called by muse, mutect2
- SV2C | c.1892C>G p.T631S | Missense Mutation (SNP) | VAF 121/515 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TLK2 | c.1606G>A p.D536N (on ENST00000326270 / NM_001284333.2; = p.D514N on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/304 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- TMOD3 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 55/292 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPM1 | c.1114C>G p.P372A | Missense Mutation (SNP) | VAF 30/573 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.017); called by muse, mutect2
- UNK | c.64C>G p.Q22E | Missense Mutation (SNP) | VAF 183/545 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- USP4 | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 51/282 reads (18%) | called by muse, mutect2, varscan2
- ZNF100 | c.358G>C p.E120Q | Missense Mutation (SNP) | VAF 33/250 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- ZNF555 | c.1730C>T p.S577L | Missense Mutation (SNP) | VAF 69/413 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- ADAMTS13 | c.3183C>T p.P1061= | Silent (SNP) | VAF 172/671 reads (26%) | catalogued as rs782251596, COSV100747008, COSV63020409; called by muse, mutect2, varscan2
- CSMD3 | c.11055C>T p.N3685= (on ENST00000297405 / NM_001363185.1; = p.N3516= on NM_052900.3) | Silent (SNP) | VAF 107/519 reads (21%) | catalogued as rs760587971, COSV52132235, COSV52260743; called by muse, mutect2, varscan2
- DEPTOR | c.429G>A p.L143= | Silent (SNP) | VAF 54/436 reads (12%) | called by muse, mutect2, varscan2
- EHBP1L1 | c.1003T>C p.L335= | Silent (SNP) | VAF 151/443 reads (34%) | catalogued as rs762193910; called by muse, mutect2, varscan2
- FAM86B2 | c.504C>T p.A168= | Silent (SNP) | VAF 136/456 reads (30%) | catalogued as rs1231843826; called by muse, varscan2
- IL15RA | c.684C>G p.L228= | Silent (SNP) | VAF 50/560 reads (9%) | called by muse, mutect2
- KCNA5 | c.786C>T p.I262= | Silent (SNP) | VAF 169/571 reads (30%) | catalogued as rs747977477; called by muse, mutect2, varscan2
- MLH1 | c.57C>T p.I19= | Silent (SNP) | VAF 93/494 reads (19%) | catalogued as rs762647509, COSV51616921, COSV51623813; called by muse, mutect2, varscan2
- NECAB2 | c.1146G>A p.T382= | Silent (SNP) | VAF 140/428 reads (33%) | catalogued as rs150498968; called by muse, varscan2
- RAVER1 | c.1569C>T p.L523= (on ENST00000615032; = p.L679= on NM_133452.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 74/433 reads (17%) | called by muse, mutect2, varscan2
- RFPL3 | c.492C>T p.D164= (on ENST00000249007 / NM_001098535.1; = p.D135= on NM_006604.2) | Silent (SNP) | VAF 76/491 reads (15%) | catalogued as rs758059430; called by muse, mutect2, varscan2
- RPUSD2 | c.597C>T p.I199= | Silent (SNP) | VAF 70/329 reads (21%) | catalogued as COSV100225281; called by muse, mutect2, varscan2
- TAS1R2 | c.2001C>T p.R667= | Silent (SNP) | VAF 157/500 reads (31%) | catalogued as rs202082109; called by muse, mutect2, varscan2
- THBD | c.138C>T p.L46= | Silent (SNP) | VAF 106/631 reads (17%) | called by muse, mutect2, varscan2
- TRIO | c.6C>T p.S2= | Silent (SNP) | VAF 21/135 reads (16%) | called by muse, mutect2, varscan2
- TRPV5 | c.1488G>A p.L496= | Silent (SNP) | VAF 94/640 reads (15%) | called by muse, mutect2, varscan2
- ZIC1 | c.324C>T p.G108= | Silent (SNP) | VAF 137/824 reads (17%) | catalogued as rs768784777, COSV99292102; called by muse, mutect2, varscan2
